CCDI case PBBUZI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/2f0ed8e7-673b-441b-9490-a545981eeea3

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Synovial sarcoma, spindle cell: ICD-O-3 morphology code: 9041/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 14.3 years (5,212 days).

Biospecimens (3 samples)
- Sample 0DHY2U: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHY3T: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHY4V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
